Gene-level copy-number profile of tumor specimen TCGA-CV-7253-01A from TCGA case TCGA-CV-7253, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.8 years (21,473 days).
Specimen TCGA-CV-7253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.2e6c028f-e6d0-47c6-8d8e-e2798cda779c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7253-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40534139-adaa-41ab-90c5-f452fb30e6ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 10,257; copy number 2: 42,482; copy number 3: 5,241; copy number 4: 288; copy number 5: 682; copy number 6: 855.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7253-01A-11D-2010-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:144,285,701–144,853,034, 1 gene (within-gene range 0–1): UTRN.
- chr6:144,706,733–144,708,497, 2 genes: AL513475.1, AL513475.2.
- chr9:2,720,469–2,844,095, 1 gene (within-gene range 0–1): PUM3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,537 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,166,914–24,004,909, 122 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:30,447,226–42,493,982, 172 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:130,560,334–198,222,513, 1,169 genes, copy number 5–6 (broad region; genes not listed).
- chr6:45,573,346–49,713,590, 54 genes, copy number 5: RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2.
- chr6:49,721,931–49,724,007, 1 gene, copy number 5 (within-gene range 3–5): AL121950.1.
- chr6:67,878,316–67,998,751, 4 genes, copy number 6: AL713998.1, AL713998.3, AL713998.4, AL713998.2.
- chr17:50,503,412–50,756,219, 15 genes, copy number 5 (within-gene range 3–5): AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3.

Autosomal genes at a single copy (total copy number 1): 7,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
